Somatic mutation profile of tumor specimen MMRF_1786_2_BM_CD138pos (aliquot MMRF_1786_2_BM_CD138pos_T1_KHS5U_L08850) from MMRF case MMRF_1786, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.1 years (17,585 days).
Specimen MMRF_1786_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f50af5c-150b-4fe5-9739-6341b0ea59af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1786_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1786_1_PB_Whole_C3_KBS5U_L05540; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/54036895-621d-4b93-9a3d-5f35f172c0c2

The open-access MAF lists 58 somatic variants for this specimen: 27 protein-altering or splice-affecting, 3 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, 3'UTR 13, Intron 8, 3'Flank 3, Nonsense Mutation 3, Silent 3, 5'UTR 2, RNA 1, 5'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 39/174 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CAMK2A | c.1423G>A p.V475I (on ENST00000348628 / NM_171825.2; = p.V486I on NM_015981.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.005); catalogued as rs771394411; called by muse, mutect2, varscan2
- CLMP | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.419); catalogued as COSV71650773; called by muse, mutect2, varscan2
- HAPLN4 | c.106G>C p.V36L | Missense Mutation (SNP) | VAF 89/177 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV52271669; called by muse, mutect2, varscan2
- HIVEP3 | c.6710A>G p.E2237G | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.154); catalogued as rs373981666; called by muse, mutect2, varscan2
- IGLV3-1 | c.88T>C p.S30P | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs535075254; called by muse, varscan2
- IQGAP3 | c.4082A>G p.N1361S | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758207580; called by muse, mutect2, varscan2
- LPL | c.655C>T p.R219* | Nonsense Mutation (SNP) | VAF 58/185 reads (31%) | catalogued as CM973710; called by muse, mutect2, varscan2
- PPARGC1A | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs767567742, COSV53531266; called by muse, mutect2, varscan2
- TRIOBP | c.6874G>A p.E2292K (on ENST00000644935 / NM_001039141.3; = p.E579K on NM_007032.5) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs945284342, COSV60378712, COSV60384308; called by muse, mutect2, varscan2
- TSC2 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1287273870; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UVSSA | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs945790378; called by muse, mutect2, varscan2
- AKT3 | c.328C>T p.Q110* | Nonsense Mutation (SNP) | VAF 37/95 reads (39%) | called by muse, mutect2, varscan2
- ALDH1B1 | c.751C>G p.Q251E | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCA2 | c.2675C>T p.S892F | Missense Mutation (SNP) | VAF 13/373 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- DNAH14 | c.9398G>T p.S3133I (on ENST00000445597; = p.S4141I on NM_001367479.1) | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- EYS | c.2567T>G p.L856R | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- IGHV1-18 | c.211_247delinsGCCACTTACAATGGTAGCACAAACTATGCACAGAAAT p.S71_L83delinsATYNGSTNYAQKF | Missense Mutation (ONP) | VAF 13/152 reads (9%) | called by muse*, pindel
- NCKAP5L | c.83G>A p.G28D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.065); called by muse, mutect2
- PGBD1 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 40/165 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PLA2R1 | c.4385A>G p.D1462G | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- SCYL1 | c.1678C>A p.P560T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- TAB1 | c.667T>C p.L223= | Splice Region (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- TRPM7 | c.2568C>G p.F856L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- WDR41 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZKSCAN8 | c.251T>A p.L84* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | called by muse, mutect2, varscan2
- ZNF709 | c.1506A>C p.K502N | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BTG1 | c.108G>A p.Q36= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs533912735, COSV55457953, COSV55458217, COSV55458575; called by muse, mutect2, varscan2
- CAPN12 | c.255G>A p.P85= | Silent (SNP) | VAF 40/172 reads (23%) | catalogued as rs201291255; called by muse, mutect2, varscan2
- SDR16C5 | c.504C>T p.D168= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as rs1179031317, COSV58129159; called by muse, mutect2, varscan2
- ADARB2 | c.*838C>T | 3'UTR (SNP) | VAF 5/36 reads (14%) | catalogued as rs11250315; called by muse, varscan2
- ANXA1 | c.-15+2311G>A | Intron (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- C11orf40 | n.244G>A | RNA (SNP) | VAF 50/96 reads (52%) | catalogued as rs1421942523; called by muse, mutect2, varscan2
- CCNDBP1 | c.250-104A>G | Intron (SNP) | VAF 11/25 reads (44%) | catalogued as rs1321870970; called by muse, varscan2
- DIO3 | c.*200G>A | 3'UTR (SNP) | VAF 45/178 reads (25%) | called by muse, mutect2, varscan2
- DMD | c.2292+1007A>G | Intron (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- EPC2 | c.460-22A>G | Intron (SNP) | VAF 32/61 reads (52%) | called by muse, varscan2
- FLRT2 | chr14:85528776 G>T | 5'Flank (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- FNIP2 | c.108-19504A>C | Intron (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- GSG1 | c.*452G>T | 3'UTR (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- HNF4G | chr8:75566024 TTCCCTTAGAAGACATT>GTTCCCTTAGAAGACATTA | 3'Flank (INS) | VAF 13/71 reads (18%) | called by pindel, varscan2*
- KIAA0232 | c.*1928_*1931dup | 3'UTR (INS) | VAF 23/66 reads (35%) | called by mutect2, pindel, varscan2
- LSM3 | c.*1215A>G | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- NTRK3 | c.*10489G>A | 3'UTR (SNP) | VAF 4/48 reads (8%) | catalogued as rs966955838, COSV69685498; called by muse, mutect2
- PDE10A | c.*955T>A | 3'UTR (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- PLEKHF2 | c.*1451A>C | 3'UTR (SNP) | VAF 15/65 reads (23%) | called by muse, mutect2, varscan2
- PPP3CA | c.-294_-271del | 5'UTR (DEL) | VAF 22/120 reads (18%) | called by mutect2, pindel
- RABGAP1 | c.*787_*788insGTATGTAT | 3'UTR (INS) | VAF 3/20 reads (15%) | catalogued as rs1554734427; called by pindel, varscan2*
- RAPGEF6 | c.*2870C>T | 3'UTR (SNP) | VAF 19/107 reads (18%) | called by muse, mutect2
- RASAL2 | c.*5260T>G | 3'UTR (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- RYR3 | c.3766-60G>A | Intron (SNP) | VAF 12/64 reads (19%) | called by mutect2, varscan2
- S100A7A | chr1:153421596 G>T | 3'Flank (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- SIRT5 | c.857+4741C>T | Intron (SNP) | VAF 32/114 reads (28%) | catalogued as rs746467087; called by muse, mutect2, varscan2
- SLC5A8 | c.-107C>T | 5'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- SOX6 | chr11:15971755 G>A | 3'Flank (SNP) | VAF 52/109 reads (48%) | catalogued as rs191595530; called by muse, mutect2, varscan2
- TFAP4 | c.823-103C>T | Intron (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- TGOLN2 | c.*2278del | 3'UTR (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- UBE2R2 | c.*60G>T | 3'UTR (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
